Gene-level copy-number profile of tumor specimen TCGA-EK-A3GM-01A from TCGA case TCGA-EK-A3GM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.4 years (23,879 days).
Specimen TCGA-EK-A3GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.b479859c-e125-475c-b410-7127f9ffddb1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A3GM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea74eef0-ba94-4f4f-b894-8ba7d797d8db

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 594; copy number 2: 17,066; copy number 3: 24,884; copy number 4: 11,067; copy number 5: 3,744; copy number 6: 1,116; copy number 7: 840; copy number 8: 72; copy number 9: 355; copy number 11: 34; copy number 13: 8; copy number 20: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A3GM-01A-11D-A20T-01): tumor purity 0.79, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,344 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,600,621–171,652,688, 2 genes, copy number 9: MYOCOS, MYOC.
- chr19:55,708,438–58,605,223, 195 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr20:9,537,370–9,839,076, 1 gene, copy number 9 (within-gene range 4–9): PAK5.
- chr20:9,835,556–62,873,076, 1,146 genes, copy number 7–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
